Somatic mutation profile of tumor specimen TCGA-VQ-A8DV-01A (aliquot TCGA-VQ-A8DV-01A-12D-A364-08) from TCGA case TCGA-VQ-A8DV, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 48.3 years (17,630 days).
Specimen TCGA-VQ-A8DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8d01d14-f774-4ea3-90bf-728c0829800a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8DV-10A (Blood Derived Normal), aliquot TCGA-VQ-A8DV-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05bca7bf-bcf5-41c2-ae85-d57f40d85530

The open-access MAF lists 78 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 2, In Frame Ins 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VPS13B | c.5295G>T p.E1765D | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs780598553, CS125684, COSV100661925; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.2104C>T p.H702Y | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1212962775, COSV99779794; called by muse, mutect2, varscan2
- APC | c.2604A>C p.E868D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99967714; called by muse, mutect2, varscan2
- ATAD5 | c.787A>C p.I263L | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100429936; called by muse, mutect2, varscan2
- BROX | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100572198; called by muse, mutect2, varscan2
- CCKAR | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs751151975, COSV55164156; called by muse, mutect2, varscan2
- CNTNAP5 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs1328491924, COSV101443495; called by muse, mutect2
- DCT | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs901996186, COSV65467485; called by muse, mutect2, varscan2
- DHX58 | c.1418G>T p.R473L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs551428365, COSV52425232, COSV99288241; called by muse, mutect2, varscan2
- DUSP26 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 18/29 reads (62%) | catalogued as rs769310192, COSV56361328; called by muse, mutect2, varscan2
- FAM135A | c.2915T>G p.I972S (on ENST00000370479 / NM_001351599.1; = p.I759S on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV99525757; called by muse, mutect2, varscan2
- FCHO1 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1036103313, COSV53186228; called by muse, mutect2, varscan2
- GABPB2 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100927223; called by muse, mutect2, varscan2
- GGN | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV99287460; called by muse, mutect2
- GHITM | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs745822967, COSV100930073, COSV64538531; called by muse, mutect2, varscan2
- GPC1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs201724796, COSV99882868; called by muse, mutect2, varscan2
- GSTA3 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as rs759597390, COSV99274529; called by muse, mutect2, varscan2
- IGHG2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as rs368941054; called by muse, mutect2, varscan2
- KCNH7 | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as rs1229855251, COSV100146782, COSV59796250; called by muse, mutect2, varscan2
- KIF26A | c.2750C>A p.A917D | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.18); PolyPhen benign (0.216); catalogued as rs1454814532, COSV100181113; called by muse, mutect2, varscan2
- KLHL13 | c.1246C>G p.P416A | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99451608; called by muse, mutect2, varscan2
- KRT35 | c.1221-1G>A p.X407_splice | Splice Site (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99877769; called by muse, mutect2, varscan2
- LGALS3 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs974856973, COSV54305832; called by muse, mutect2, varscan2
- MEGF8 | c.4145G>A p.G1382E (on ENST00000251268 / NM_001271938.2; = p.G1315E on NM_001410.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210632145, COSV99236082; called by muse, mutect2, varscan2
- MFN1 | c.1634T>G p.L545R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV99764426; called by muse, mutect2, varscan2
- MSR1 | c.217+2T>A p.X73_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100027221; called by muse, varscan2
- MYH9 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV99338732; called by muse, mutect2, varscan2
- MYO16 | c.5144C>T p.T1715M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs375722670; called by muse, mutect2, varscan2
- NPAP1 | c.2471A>T p.D824V | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100275334; called by muse, mutect2, varscan2
- NPIPA1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs747382403; called by muse, mutect2, varscan2
- NUP155 | c.1078G>T p.A360S (on ENST00000231498 / NM_153485.3; = p.A301S on NM_004298.4) | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99192788; called by muse, mutect2, varscan2
- ODF3L1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.397); catalogued as rs1357354190, COSV100150771; called by muse, mutect2, varscan2
- OR51I2 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58298913, COSV58300081; called by muse, mutect2, varscan2
- PCDH15 | c.2131A>G p.N711D | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs761496988, COSV57287263; called by muse, mutect2, varscan2
- PCDH8 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV58811775; called by muse, mutect2
- PFKL | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as rs373338252; called by muse, mutect2, varscan2
- SDHA | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs143484394; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG7 | c.2768A>T p.E923V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV100750281; called by muse, mutect2, varscan2
- SNX25 | c.1543A>C p.T515P | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.56); catalogued as COSV99252822; called by muse, mutect2, varscan2
- SYNE1 | c.12812C>T p.T4271I (on ENST00000367255 / NM_182961.4; = p.T4200I on NM_033071.3) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1317228570, COSV99563167; called by muse, mutect2, varscan2
- TAS2R46 | c.892A>T p.R298W | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101114752; called by muse, mutect2, varscan2
- TNNT3 | c.799C>T p.R267C (on ENST00000397301 / NM_001367846.1; = p.R256C on NM_006757.4) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs766438980, COSV99548334; called by muse, mutect2, varscan2
- TTF2 | c.2822A>C p.E941A | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101037476; called by muse, mutect2, varscan2
- UQCRC1 | c.209C>A p.T70K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99178971; called by muse, mutect2, varscan2
- VPS13D | c.12283G>A p.G4095R | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139271621; called by muse, mutect2, varscan2
- ZIM2 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55635961, COSV99688836; called by muse, mutect2, varscan2
- ZKSCAN3 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99356910; called by muse, mutect2, varscan2
- ZNF254 | c.1069A>T p.K357* | Nonsense Mutation (SNP) | VAF 28/113 reads (25%) | catalogued as COSV100741615; called by muse, mutect2, varscan2
- ZNF667 | c.1172G>T p.C391F | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99410423; called by muse, mutect2, varscan2
- ZNF786 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs757197778, COSV100302836; called by muse, mutect2, varscan2
- ZNFX1 | c.2005A>G p.I669V | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100870835; called by muse, mutect2, varscan2
- ZP1 | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99612396; called by muse, mutect2, varscan2
- ADTRP | c.136_137dup p.M46Ifs*2 | Frame Shift Ins (INS) | VAF 90/216 reads (42%) | called by mutect2, pindel, varscan2
- ASIC5 | c.952del p.E318Nfs*7 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by pindel, varscan2
- DNAH10 | c.12907_12909delinsGA p.F4303Efs*8 (on ENST00000409039; = p.F4242Efs*8 on NM_207437.3) | Frame Shift Del (DEL) | VAF 40/119 reads (34%) | called by pindel, varscan2*
- KATNB1 | c.1181_1183dup p.R394dup | In Frame Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- MUC6 | c.6108del p.S2037Pfs*28 | Frame Shift Del (DEL) | VAF 69/332 reads (21%) | called by pindel, varscan2
- TP53 | c.384_387dup p.L130Cfs*20 | Frame Shift Ins (INS) | VAF 14/28 reads (50%) | called by mutect2, pindel, varscan2
- TUBA3D | c.1100_1110del p.D367Gfs*24 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- ZNF112 | c.2339_2343del p.E780Vfs*7 (on ENST00000337401 / NM_001083335.2; = p.E774Vfs*7 on NM_013380.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 98/273 reads (36%) | called by mutect2, pindel, varscan2
- CSF3 | c.519C>T p.F173= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs774912212, COSV56641658; ClinVar: benign; called by muse, mutect2, varscan2
- DLGAP2 | c.759C>T p.N253= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1229676759, COSV70102308; called by muse, mutect2
- HP1BP3 | c.1554A>G p.K518= | Silent (SNP) | VAF 64/89 reads (72%) | catalogued as COSV100391829; called by muse, mutect2, varscan2
- HRNR | c.2169C>T p.S723= | Silent (SNP) | VAF 74/271 reads (27%) | catalogued as COSV100913434; called by muse, mutect2, varscan2
- KLHL10 | c.1245C>T p.L415= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs200538026, COSV99509503; called by muse, mutect2, varscan2
- MAEA | c.861C>T p.T287= (on ENST00000303400 / NM_001017405.3; = p.T246= on NM_005882.5) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1464930884, COSV99295437; called by muse, mutect2, varscan2
- MTHFD1 | c.2394G>A p.L798= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV99386886; called by muse, mutect2, varscan2
- OR2M4 | c.219C>A p.L73= | Silent (SNP) | VAF 7/158 reads (4%) | catalogued as COSV100141201, COSV60710145; called by muse, mutect2
- PNPLA2 | c.564G>A p.S188= | Silent (SNP) | VAF 68/93 reads (73%) | catalogued as rs149864883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM10 | c.222G>A p.V74= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as COSV100702027; called by muse, mutect2, varscan2
- PRICKLE4 | c.1026C>T p.T342= (on ENST00000359201; = p.T382= on NM_013397.6) | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1245566875, COSV100138734; called by muse, mutect2, varscan2
- RBFOX1 | c.480C>T p.F160= | Silent (SNP) | VAF 49/88 reads (56%) | catalogued as rs919248039, COSV60946947; called by muse, mutect2, varscan2
- SLC26A4 | c.1068C>T p.I356= | Silent (SNP) | VAF 91/157 reads (58%) | catalogued as rs886061885, COSV55917556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPEN | c.2397G>T p.P799= | Silent (SNP) | VAF 55/86 reads (64%) | catalogued as COSV101005212, COSV65367862; called by muse, mutect2, varscan2
- TMEM132D | c.2428A>C p.R810= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV101242808; called by muse, mutect2, varscan2
- TRPC1 | c.876C>T p.D292= (on ENST00000476941 / NM_001251845.2; = p.D258= on NM_003304.4) | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs112064817; called by muse, mutect2, varscan2
- AL109984.1 | n.186+4925C>T | Intron (SNP) | VAF 16/232 reads (7%) | catalogued as rs775231013, COSV63751185; called by muse, mutect2
- AL353804.7 | chrX:73852036 C>T | 3'Flank (SNP) | VAF 6/9 reads (67%) | catalogued as rs1178278001; called by muse, mutect2, varscan2
